CGCI case BLGSP-71-19-00106 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b06f7bf0-45bb-4aca-8f22-72d8a4f73f99

Demographics
Sex at birth: male; Race: white; Age at index: 8 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Testis, NOS; Classification of tumor: primary; Age at diagnosis: 8.2 years (3,003 days); Year of diagnosis: 1987; Ann Arbor pathologic stage: Stage III; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 11,033 days (30.2 years); Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, pediatric; Max tumor bulk site: Other; Sites of involvement: Abdomen.
   Pathology details: Bone marrow malignant cells: No.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (3 entries)
- Days to follow up: 248 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Testis, NOS; Days to progression: 248 days; Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Days to follow up: 11,033 days (30.2 years); Disease response: Tumor Free.
- Follow-up contacts recording only the day: day 0, day 10,955.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- Lactate Dehydrogenase 242 [Blood test normal range upper: 260].

Other clinical attributes
- Day 0: Weight: 29.8 kg; Height: 133 cm; BMI: 16.8.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-19-00106-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-19-00106-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Biospecimen anatomic site: Testis; Preservation method: Frozen; Days to sample procurement: 248 days; Method of sample procurement: Excisional Biopsy; Tissue collection type: Retrospective.
  Slide BLGSP-71-19-00106-02A-01-S1-HE: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 15; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 0.
  Slide BLGSP-71-19-00106-02A-01-S2-HE: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 0.
- Sample BLGSP-71-19-00106-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Lymphocytes; Preservation method: Frozen; Days to sample procurement: 9,263 days (25.4 years); Method of sample procurement: Blood Draw; Tissue collection type: Retrospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- Primary pathology: Histologic diagnosis: small non-cleaved cell burkitts type; Extranodal site involvement: 1; Extranodal involvment other: Abdom mass; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: No Known Nodal Involvement.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 242.
- New tumor event: New tumor event type: Distant Metastasis; New tumor event site other: testicle; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes.
- Follow-up form: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
